Somatic mutation profile of tumor specimen MP2PRT-PASRMH-TMP1-A (aliquot MP2PRT-PASRMH-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASRMH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 2.3 years (840 days).
Specimen MP2PRT-PASRMH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee745c5a-d4e6-4c2f-97d7-a036c7d4f99b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRMH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRMH-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4ddc8ac-19e3-42e4-a46d-1642ba5f1286

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 62/668 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AGAP1 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 56/546 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.146); catalogued as rs767939918; called by muse, mutect2
- C11orf65 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 24/246 reads (10%) | catalogued as rs772485445, COSV101262713, COSV67599038; called by muse, varscan2
- CDH6 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 231/509 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773139830, COSV99419265; called by muse, mutect2, varscan2
- CR1 | c.4175G>A p.R1392H | Missense Mutation (SNP) | VAF 82/362 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.738); catalogued as rs200621891, COSV65462323; called by muse, mutect2, varscan2
- ZFHX4 | c.5641G>A p.E1881K | Missense Mutation (SNP) | VAF 25/487 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as rs1227747539, COSV99264401; called by muse, mutect2
- AC013489.1 | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 36/635 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.115); called by muse, mutect2
- ALDH1A2 | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BAZ1A | c.4115C>T p.P1372L | Missense Mutation (SNP) | VAF 164/386 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA1217 | c.1977G>T p.Q659H | Missense Mutation (SNP) | VAF 32/470 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYOT | c.1079T>G p.V360G | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- HSD17B8 | c.669G>A p.P223= | Silent (SNP) | VAF 31/648 reads (5%) | catalogued as rs553229947, COSV63002797; called by muse, mutect2
- ZNF324 | c.1596A>T p.P532= | Silent (SNP) | VAF 28/693 reads (4%) | called by muse, mutect2
- IGKV1OR2-108 | chr2:113406872 ins AAAGGC | 3'Flank (INS) | VAF 65/198 reads (33%) | called by mutect2, pindel, varscan2
